Somatic mutation profile of tumor specimen TCGA-W5-AA38-01A (aliquot TCGA-W5-AA38-01A-11D-A417-09) from TCGA case TCGA-W5-AA38, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.5 years (20,285 days).
Specimen TCGA-W5-AA38-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d62db753-3b1d-4647-92f1-d97fda231b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA38-10A (Blood Derived Normal), aliquot TCGA-W5-AA38-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f829552-f788-4b99-aada-97a7c2608fbc

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV65560659; called by muse, mutect2, varscan2
- DNM2 | c.2593G>A p.E865K (on ENST00000355667 / NM_001005360.3; = p.E861K on NM_004945.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as rs746818628, COSV53035117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETS1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1045241125, COSV60091363; called by muse, mutect2, varscan2
- GSDMA | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1449146373; called by muse, mutect2, varscan2
- NPM3 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1221197409; called by muse, mutect2, varscan2
- PBRM1 | c.1468A>T p.R490* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV56314468; called by muse, mutect2, varscan2
- PCDH10 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52096775; called by muse, mutect2, varscan2
- SORCS3 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV100863486; called by muse, mutect2, varscan2
- VPS52 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs765485457, COSV71403442; called by mutect2, varscan2
- ZNF99 | c.1759C>A p.H587N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68054867; called by muse, mutect2
- ZPBP2 | c.586G>C p.E196Q (on ENST00000348931 / NM_199321.3; = p.E174Q on NM_198844.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62375468; called by muse, mutect2
- BCHE | c.1142del p.G381Vfs*2 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- CLEC14A | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2
- FRMPD3 | c.3191C>T p.S1064F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MOCOS | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2
- PPCS | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMEM31 | c.33dup p.Q12Tfs*8 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- TPR | c.3613C>T p.R1205* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- TRIM33 | c.2176C>A p.L726I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- TTC3 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- UBE3A | c.2139del p.F713Lfs*14 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- DNASE1L2 | c.642G>C p.A214= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- RIMS2 | c.822T>G p.A274= (on ENST00000666250 / NM_001348490.2; = p.A82= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV51703307; called by muse, mutect2, varscan2
- RP1 | c.984C>T p.D328= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs776574526, COSV55113924; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBA3C | c.624C>A p.A208= | Silent (SNP) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- VANGL1 | c.699C>A p.I233= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
